Somatic mutation profile of tumor specimen TCGA-AH-6547-01A (aliquot TCGA-AH-6547-01A-11D-1826-10) from TCGA case TCGA-AH-6547, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 79.5 years (29,030 days).
Specimen TCGA-AH-6547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d31d0e6-6e64-469d-bd67-b673987dd71c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6547-11A (Solid Tissue Normal), aliquot TCGA-AH-6547-11A-02D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/606232b2-c1f9-46de-a0e5-e0323f0472ab

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STYXL2 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV99608967; called by muse, varscan2
- SLC44A1 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.763); called by muse, mutect2
